Somatic mutation profile of tumor specimen ALCH-B4Y2-TTP1-A (aliquot ALCH-B4Y2-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4Y2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.1 years (20,838 days).
Specimen ALCH-B4Y2-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e442e92-8294-40f2-80d0-bf5ac8d6f015.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4Y2-NB1-A (Blood Derived Normal), aliquot ALCH-B4Y2-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ca0c820-a79a-46dd-b950-212c2b028a1e

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, 5'UTR 2, RNA 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60101901; called by muse, mutect2, varscan2
- C10orf71 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs754197819, COSV60504037; called by muse, mutect2
- LPO | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 66/555 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs376369411; called by muse, mutect2, varscan2
- MRM1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs750600798; called by muse, mutect2
- OTOG | c.5849C>T p.T1950M | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs758489218; ClinVar: likely benign; called by muse, mutect2
- PHTF2 | c.911G>A p.R304Q (on ENST00000248550 / NM_001366089.1; = p.R266Q on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs368157181; called by muse, mutect2, varscan2
- SLC25A23 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs748515868, COSV51197391; called by muse, mutect2, varscan2
- TCF4 | c.41A>C p.K14T | Missense Mutation (SNP) | VAF 50/622 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV61906813; called by muse, mutect2
- ZNF571 | c.1096A>G p.K366E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as rs1266794503; called by muse, mutect2, varscan2
- ANKRD11 | c.7720G>A p.E2574K | Missense Mutation (SNP) | VAF 41/479 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2
- CABS1 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- CD300LG | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CSMD1 | c.7177A>C p.S2393R (on ENST00000520002; = p.S2392R on NM_033225.6) | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM181B | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KRBA2 | c.664A>T p.N222Y | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- MMUT | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 31/321 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NOS3 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPA1 | c.132T>A p.H44Q | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.085); called by muse, mutect2
- OR2AJ1 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PSMD8 | c.915+5C>T | Splice Region (SNP) | VAF 28/282 reads (10%) | called by muse, mutect2
- SEC14L1 | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SETD1B | c.4612C>T p.R1538* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- APLP1 | c.567C>T p.H189= | Silent (SNP) | VAF 30/307 reads (10%) | catalogued as rs775609998; called by muse, mutect2
- CSMD3 | c.9024C>T p.G3008= (on ENST00000297405 / NM_001363185.1; = p.G2839= on NM_052900.3) | Silent (SNP) | VAF 43/437 reads (10%) | catalogued as rs781064703, COSV52135104; called by muse, mutect2, varscan2
- IFITM10 | c.69T>A p.A23= | Silent (SNP) | VAF 26/601 reads (4%) | called by muse, mutect2
- KRTAP10-9 | c.138C>T p.V46= | Silent (SNP) | VAF 44/539 reads (8%) | catalogued as rs1555934590; called by muse, mutect2
- MAGEB18 | c.180C>T p.I60= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs866611358, COSV57463549; called by muse, mutect2, varscan2
- TIAM1 | c.4209C>G p.L1403= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs1278395226; called by muse, mutect2, varscan2
- SSPOP | n.1157C>T | RNA (SNP) | VAF 26/292 reads (9%) | catalogued as rs753578940; called by muse, mutect2
- SSPOP | n.9773C>T | RNA (SNP) | VAF 33/284 reads (12%) | catalogued as rs570968212, COSV65136935; called by muse, mutect2, varscan2
- WAPL | c.-326G>A | 5'UTR (SNP) | VAF 51/491 reads (10%) | catalogued as rs1417397597; called by muse, mutect2, varscan2
- WDR55 | c.-9C>T | 5'UTR (SNP) | VAF 23/225 reads (10%) | catalogued as rs1212361331; called by muse, mutect2, varscan2
